Somatic mutation profile of tumor specimen 0DPJTC from CCDI case PBCDVY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pleomorphic xanthoastrocytoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 13.5 years (4,936 days).
Specimen 0DPJTC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3abfef1c-ddde-4d24-9bb4-3eb380c33ade.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPJSE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe23000c-be20-43fb-a371-83bb5ea2018d

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 320/930 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- HGH1 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 20/520 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1181818444; called by muse, mutect2
- ITIH3 | c.2329G>A p.V777I | Missense Mutation (SNP) | VAF 139/478 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as rs774168963, COSV69649042; called by muse, mutect2, varscan2
- NLRC4 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 16/399 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs1317272776, COSV61593413; ClinVar: uncertain significance; called by muse, mutect2
- ASGR1 | c.756C>T p.G252= | Silent (SNP) | VAF 55/534 reads (10%) | called by muse, mutect2, varscan2
- MIGA1 | c.693C>T p.R231= | Silent (SNP) | VAF 72/880 reads (8%) | called by muse, mutect2
